Somatic mutation profile of tumor specimen TCGA-DE-A2OL-01A (aliquot TCGA-DE-A2OL-01A-11D-A18F-08) from TCGA case TCGA-DE-A2OL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 44.5 years (16,253 days).
Specimen TCGA-DE-A2OL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed8ef16a-8931-4ba4-a1e6-ddd088354f59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A2OL-10A (Blood Derived Normal), aliquot TCGA-DE-A2OL-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7be7ba73-0c4b-4c19-8eb5-03bb6c425576

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RGL2 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1181183497, COSV65842852; called by muse, mutect2, varscan2
- STK32B | c.1024A>C p.K342Q | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.924); catalogued as COSV51506957; called by muse, mutect2
- TEAD4 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV63282138; called by muse, mutect2, varscan2
- TLR4 | c.1013T>C p.V338A (on ENST00000355622 / NM_138554.5; = p.V298A on NM_003266.4) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.13); catalogued as COSV62924055; called by muse, mutect2, varscan2
- TUBB4B | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as COSV61116759, COSV61118562; called by muse, mutect2, varscan2
- UBASH3A | c.1046G>T p.R349M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52315401; called by muse, varscan2
- DOK6 | c.73del p.R25Dfs*18 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
